Gene-level copy-number profile of tumor specimen HTMCP-03-06-02103-01B from CGCI case HTMCP-03-06-02103, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3.
Specimen HTMCP-03-06-02103-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6231e8d8-7aea-427b-adef-62db73751df4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02103-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,267 have no estimate.
https://portal.gdc.cancer.gov/files/461b4baa-404e-459d-901b-246e0d5da87d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 1,232; copy number 2: 21,073; copy number 3: 24,606; copy number 4: 8,078; copy number 5: 2,569; copy number 6: 25; copy number 7: 539; copy number 8: 147; copy number 11: 5; copy number 12: 25; copy number 15: 3; copy number 35: 1; copy number 48: 1.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:21,987,481–21,987,919, 2 genes (within-gene range 0–3): RN7SL386P, RNU6-1022P.
- chr1:120,489,860–120,842,110, 5 genes (within-gene range 0–1): AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26.
- chr1:120,913,184–121,185,539, 14 genes (within-gene range 0–4): LINC00623, RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B.
- chr1:149,676,851–149,747,818, 2 genes (within-gene range 0–1): AC243772.3, RNU1-68P.
- chr1:223,947,605–223,950,416, 1 gene: CICP5.
- chr2:89,884,740–89,907,246, 4 genes: IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34.
- chr2:91,578,478–91,621,421, 3 genes (within-gene range 0–1): AC233266.1, AC233266.2, AC116050.1.
- chr2:91,736,726–91,781,169, 4 genes: AC027612.1, KMT5AP2, AC027612.3, GGT8P.
- chr7:74,894,116–74,913,310, 3 genes: PMS2P5, Y_RNA, SPDYE12P.
- chr7:75,493,625–75,504,304, 1 gene (within-gene range 0–3): SPDYE5.
- chr11:90,098,421–90,098,817, 1 gene: AP000648.2.
- chr14:85,202,849–85,239,474, 1 gene: AL357172.1.
- chr17:46,558,830–46,562,795, 1 gene (within-gene range 0–2): FAM215B.
- chr18:15,075,445–15,122,767, 1 gene: AP005242.1.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:15,282,557–15,350,043, 5 genes: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 721 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–667,168, 25 genes, copy number 7 (within-gene range 4–7): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72.
- chr5:710,355–45,895,970, 652 genes, copy number 7–8 (broad region; genes not listed).
- chr6:85,777,639–85,777,755, 1 gene, copy number 7: Y_RNA.
- chr7:54,759,348–55,588,336, 11 genes, copy number 12 (within-gene range 3–12): SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1.
- chr7:73,593,194–74,122,525, 18 genes, copy number 11–12: MLXIPL, AC005089.1, VPS37D, DNAJC30, BUD23, STX1A, MIR4284, RN7SL265P, ABHD11-AS1, ABHD11, CLDN3, CLDN4, METTL27, TMEM270, AC099398.1, ELN, ELN-AS1, LIMK1.
- chr8:7,190,901–7,191,563, 1 gene, copy number 11: RPS3AP33.
- chr8:12,290,071–12,345,776, 4 genes, copy number 7–48: DEFB131D, DEFB130A, RNA5SP254, DEFB108E.
- chr14:19,681,420–19,700,650, 3 genes, copy number 15 (within-gene range 2–15): AL512310.2, ARHGAP42P4, AL512310.1.
- chr19:43,192,702–43,269,530, 3 genes, copy number 7: PSG4, CEACAMP10, PSG9.
- chr22:18,636,445–18,653,617, 2 genes, copy number 8: CA15P2, PPP1R26P2.
- chr22:18,733,914–18,757,906, 1 gene, copy number 8: FAM230E.

Autosomal genes at a single copy (total copy number 1): 1,232. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
